Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4998, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4998-01A (Primary Tumor).

[page 1 of 2]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

TCGA - BP - 4998

Clinical Diagnosis & History:

with incidental right renal mass.

Specimens Submitted:

1: SP:Kidney, right, partial nephrectomy

DIAGNOSIS:

1. SP:Kidney, right, partial nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 3.5 cm.

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Simple cortical cysts, interstitial chronic inflammation

Adrenal Gland:

Not Identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

2. Kidney, lateral lower pole cyst wall, excision :

Benign renal tubules and fibrovascular tissue with hemosiderin-laden macrophages.

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	CHR	
	SYN	
	NEG CONT	
	IMM RECUT	

Gross Description:

1.) The specimen is received fresh and is labeled "right partial nephrectomy, stitch marks the medial cysts". It consists of a 8.0 x 6.8 x 4.1 cm wedge shaped portion of kidney with a suture marking a cyst at the margin. The margin is inked black and the specimen is serially sectioned to reveal a circumscribed mass measuring 3.5 x 3.1 x 2.8 cm, bulging through the surface of the renal parenchyma. Sectioning through the mass reveals heterogeneous cut surfaces with cystic areas, hemorrhagic areas and golden tan solid areas. The clearance from the resection margin is 0.5 cm. Sectioning through the area of the suture reveals a portion of the cyst measuring 0.8 cm in greatest dimension, extending to the black inked surgical margin. Attached perirenal fat measures 11.5 x 8 x 3 cm. Representatively submitted. Portions of the tumor are submitted for TPS. A gross photograph is taken.

Summary of sections:

T - tumor
TM - tumor in relation to margin
CS - cyst and renal parenchyma in area of suture
K - unremarkable kidney

2). The specimen is received in formalin labeled, "left lateral lower pole cyst wall" and consists of single fragment of pink-tan soft tissue measuring of 0.2 cm in greatest dimension. Submitted in toto.

Summary of section:

U-undesigned

Summary of Sections:

Part 1: SP:Kidney, right, partial nephrectomy

Block	Sect. Site	PCs
3	CS	4
1	K	1
3	T	5
3	TM	3

Part 2: SP:Kidney, lateral lower pole cyst wall, excision

Block	Sect. Site	PCs
1	U	1

Source: NCI Genomic Data Commons file 1ffca9bf-9ec4-4211-b4d8-f609a0774a33 (TCGA-BP-4998.BB5F3B00-EFB5-4A61-BBDD-CBF3BD3BAD2B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).